Gene-level copy-number profile of tumor specimen TCGA-Z4-AAPG-01A from TCGA case TCGA-Z4-AAPG, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 64.0 years (23,390 days).
Specimen TCGA-Z4-AAPG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.c741954e-5f29-4345-829d-c00ff3b5480a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-Z4-AAPG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8704baf6-8a16-4bb4-8653-68ad71f8621a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 258; copy number 1: 41; copy number 2: 20,064; copy number 3: 19,431; copy number 4: 15,470; copy number 5: 3,709; copy number 6: 479; copy number 7: 275; copy number 8: 64; copy number 10: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-Z4-AAPG-01A-11D-A38Y-01): tumor purity 0.8, ploidy 3.07, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 258 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:175,059,361–175,271,096, 3 genes: EEF1B2P8, NAALADL2-AS3, NAALADL2-AS2.
- chr8:150,584–7,187,316, 115 genes (within-gene range 0–2) (broad region; genes not listed).
- chr8:10,433,672–12,015,193, 64 genes (broad region; genes not listed).
- chr8:13,536,029–13,632,574, 4 genes: RNA5SP255, C8orf48, AC022832.1, AC022832.2.
- chr9:20,658,309–21,699,596, 44 genes: FOCAD, FOCAD-AS1, MIR491, SNORA30B, HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): AL359922.1, TUBB8P1.
- chr9:21,966,929–22,128,103, 7 genes (within-gene range 0–2): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr9:23,826,491–26,892,803, 19 genes (within-gene range 0–2): AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 354 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,055,033–1,724,357, 64 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr5:24,352,309–26,013,025, 27 genes, copy number 7–10: AC010387.1, Metazoa_SRP, AC010387.2, CDH10, AC091885.2, AC091885.1, AC091893.2, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, AC113370.1, RNU4-43P.
- chr17:14,374,139–14,421,472, 1 gene, copy number 7: AC022816.1.
- chr19:7,886,977–11,079,426, 168 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr20:55,074,644–59,113,631, 94 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 41. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
